CCDI case PBCNWG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/beac3bee-60ed-4f3d-9d35-0baa3c07578e

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 2.9 years (1,075 days).

Biospecimens (3 samples)
- Sample 0DWBC3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWBCE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWBCQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
